Somatic mutation profile of tumor specimen TARGET-10-PAKSWW-60A (aliquot TARGET-10-PAKSWW-60A-01D) from TARGET case TARGET-10-PAKSWW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.1 years (5,516 days).
Specimen TARGET-10-PAKSWW-60A: Sample type: Primary Xenograft Tissue; Tissue type: Tumor; Tumor descriptor: Xenograft.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6213b347-7491-4ec2-a7a5-58bbd5b2329a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAKSWW-10A (Blood Derived Normal), aliquot TARGET-10-PAKSWW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c679f4f7-410f-4e4c-9da7-d0cb82e1c4a1

The open-access MAF lists 26 somatic variants for this specimen: 18 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 17, Silent 8, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 173/370 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 78/78 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AEBP1 | c.3187A>G p.T1063A | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.023); catalogued as COSV56258757; called by muse, mutect2
- BMS1 | c.2656G>A p.V886I | Missense Mutation (SNP) | VAF 24/361 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs771571475, COSV65735802; called by muse, mutect2
- DNAH7 | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 193/362 reads (53%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.714); catalogued as rs769106832, COSV56764893; called by muse, mutect2, varscan2
- DNAH9 | c.2711A>T p.K904M | Missense Mutation (SNP) | VAF 71/526 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.289); catalogued as COSV52355253; called by muse, mutect2, varscan2
- DOT1L | c.140A>T p.E47V | Missense Mutation (SNP) | VAF 578/580 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67108264; called by muse, mutect2, varscan2
- EMP2 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 62/136 reads (46%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs749960492, COSV63996073; called by muse, mutect2, varscan2
- FAM83B | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs373419492; called by muse, mutect2
- GRID1 | c.2876C>T p.A959V | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.058); catalogued as rs777631027; called by muse, mutect2, varscan2
- MUCL3 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.082); catalogued as rs889638489, COSV99079634; called by muse, mutect2
- SMC1A | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 65/65 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59131159; called by muse, mutect2, varscan2
- TFEC | c.515+1G>A p.X172_splice | Splice Site (SNP) | VAF 115/284 reads (40%) | catalogued as rs1377961775, COSV55398914; called by muse, mutect2, varscan2
- TIPRL | c.355A>G p.T119A | Missense Mutation (SNP) | VAF 187/362 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63207902; called by muse, mutect2, varscan2
- OR6B1 | c.619T>G p.F207V | Missense Mutation (SNP) | VAF 180/410 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC4A9 | c.805C>A p.L269I (on ENST00000507527 / NM_001258428.2; = p.L245I on NM_031467.3) | Missense Mutation (SNP) | VAF 10/288 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.327); called by muse, mutect2
- SULT2B1 | c.662T>A p.V221E (on ENST00000201586 / NM_177973.2; = p.V206E on NM_004605.2) | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF57 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- ARHGAP42 | c.2097A>C p.S699= | Silent (SNP) | VAF 46/75 reads (61%) | called by muse, mutect2, varscan2
- CADPS2 | c.1134G>A p.K378= | Silent (SNP) | VAF 170/356 reads (48%) | called by muse, mutect2, varscan2
- FTCD | c.117C>T p.D39= | Silent (SNP) | VAF 13/18 reads (72%) | catalogued as rs751420192; called by muse, mutect2, varscan2
- HDAC4 | c.3042C>T p.V1014= | Silent (SNP) | VAF 25/297 reads (8%) | called by muse, mutect2
- KCNK10 | c.1314G>A p.A438= | Silent (SNP) | VAF 10/130 reads (8%) | catalogued as rs762061253; called by muse, mutect2
- SLC23A1 | c.1401C>T p.F467= | Silent (SNP) | VAF 46/90 reads (51%) | called by muse, mutect2, varscan2
- STXBP5 | c.537C>T p.Y179= | Silent (SNP) | VAF 226/465 reads (49%) | catalogued as rs750040194; called by muse, mutect2, varscan2
- TRHDE | c.630C>T p.L210= | Silent (SNP) | VAF 18/37 reads (49%) | called by muse, mutect2, varscan2
